Gene-level copy-number profile of tumor specimen TCGA-NH-A6GB-01A from TCGA case TCGA-NH-A6GB, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.5 years (26,100 days).
Specimen TCGA-NH-A6GB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.422fa025-16c8-482a-9691-8f97c7bde5ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NH-A6GB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/43fa0e24-15f8-46f8-810d-dc8c68e3827f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 4,037; copy number 3: 898; copy number 4: 39,250; copy number 5: 9,446; copy number 6: 29; copy number 7: 2,120; copy number 8: 21; copy number 9: 1,128; copy number 10: 1,174; copy number 11: 3; copy number 12: 1,306; copy number 13: 390; copy number 15: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NH-A6GB-01A-11D-A36W-01): tumor purity 0.69, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,012 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,269,704–38,382,272, 1 gene, copy number 15 (within-gene range 5–15): NSD3.
- chr8:38,335,981–38,601,200, 10 genes, copy number 15: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1.
- chr8:39,309,909–40,172,612, 18 genes, copy number 10–12: AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:43,018,424–145,066,685, 1,562 genes, copy number 9–10 (broad region; genes not listed).
- chr13:18,467,172–35,673,022, 363 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr13:36,168,217–114,337,626, 1,026 genes, copy number 12–13 (broad region; genes not listed).
- chr20:21,530,122–51,562,831, 736 genes, copy number 9–10 (within-gene range 5–10) (broad region; genes not listed).
- chr20:52,192,159–54,859,812, 35 genes, copy number 13: LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P.
- chr20:55,408,898–55,684,915, 3 genes, copy number 11 (within-gene range 8–11): LINC01440, LINC01441, AL160413.1.
- chr20:55,997,357–64,313,132, 258 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
